Somatic mutation profile of tumor specimen MMRF_2531_2_PB_CD138pos (aliquot MMRF_2531_2_PB_CD138pos_T2_KHS5U_L16588) from MMRF case MMRF_2531, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.5 years (25,765 days).
Specimen MMRF_2531_2_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 016cd7bf-d518-4a3b-9b22-40bf467e9818.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2531_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2531_1_PB_CD3pos_C5_KHS5U_K15148; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94d2c755-7e88-4d63-8e6a-826a9acc818a

The open-access MAF lists 137 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 43, Missense Mutation 38, Intron 17, Silent 12, 5'UTR 8, RNA 4, Nonsense Mutation 4, Splice Site 4, Frame Shift Del 3, 3'Flank 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 64/70 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC11 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as rs1189976702; called by muse, mutect2, varscan2
- AKAP17A | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1204041488; called by muse, mutect2, varscan2
- AKR1B10 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.643); catalogued as rs769711685; called by mutect2, varscan2
- AL645922.1 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs547881286, COSV54963054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATL3 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as rs767260184; called by muse, mutect2, varscan2
- CASP4 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs147548594, COSV67744743; called by muse, mutect2, varscan2
- CIC | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs200040001; called by muse, mutect2, varscan2
- IGHV2-70 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs144976346; called by muse, varscan2
- IGLV3-1 | c.203A>C p.Q68P | Missense Mutation (SNP) | VAF 62/72 reads (86%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs373323725; called by muse, mutect2, varscan2
- INTS1 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as rs1343068610; called by muse, mutect2, varscan2
- KRTAP13-4 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61878454; called by muse, mutect2, varscan2
- KYNU | c.1080A>T p.K360N | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51580158; called by muse, mutect2, varscan2
- LRRC72 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1357337462; called by muse, mutect2, varscan2
- LRRC8B | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV58376910; called by muse, mutect2, varscan2
- OLA1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV52974073; called by muse, mutect2, varscan2
- PCDH17 | c.1223del p.G408Vfs*18 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | catalogued as COSV64974164; called by mutect2, pindel, varscan2
- PSMC6 | c.241del p.E81Kfs*26 (on ENST00000612399; = p.E67Kfs*26 on NM_002806.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as COSV71629412; called by mutect2, pindel
- RHOBTB3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as rs768905935, COSV66102659; called by muse, mutect2, varscan2
- TRRAP | c.9511C>T p.R3171W (on ENST00000359863 / NM_001244580.1; = p.R3142W on NM_003496.3) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778465879, COSV62838500; called by muse, mutect2, varscan2
- ZNF165 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV66103120; called by muse, mutect2, varscan2
- A2M | c.599A>T p.Q200L | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACE | c.3279C>T p.L1093= | Splice Region (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- BRD4 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2
- CENPO | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBBP | c.3366T>G p.I1122M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- DPCD | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP1 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- FGD5 | c.3154+1G>T p.X1052_splice | Splice Site (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2, varscan2
- G6PC2 | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- IQCH | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 83/166 reads (50%) | called by muse, mutect2, varscan2
- IRX3 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- ITIH5 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL36 | c.1631G>A p.W544* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- LTB | c.163-2A>C p.X55_splice | Splice Site (SNP) | VAF 168/351 reads (48%) | called by muse, mutect2, varscan2
- MBIP | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- METTL8 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NT5C1B | c.774G>T p.Q258H (on ENST00000359846 / NM_001199086.2; = p.Q198H on NM_033253.4) | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPE1 | c.1276C>A p.L426I (on ENST00000424269; = p.L284I on NM_152315.5) | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIPOX | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PLEKHA5 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PLEKHG4B | c.2947G>A p.D983N (on ENST00000283426; = p.D1339N on NM_052909.5) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRDM1 | c.2027T>G p.L676R | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A1 | c.370+1G>A p.X124_splice | Splice Site (SNP) | VAF 26/29 reads (90%) | called by muse, varscan2
- TPGS1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by mutect2, varscan2
- TRIM41 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTC7B | c.1647del p.N550Tfs*20 | Frame Shift Del (DEL) | VAF 35/88 reads (40%) | called by mutect2, pindel, varscan2
- UBE2J1 | c.27T>G p.S9R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- USP42 | c.2112G>T p.M704I | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWA5B1 | c.2341A>T p.T781S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP10B | c.1602G>A p.V534= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs1338032971; called by muse, mutect2, varscan2
- FNDC3B | c.2019A>G p.Q673= | Silent (SNP) | VAF 51/103 reads (50%) | catalogued as rs775169168; called by muse, mutect2, varscan2
- KIF26A | c.1038G>A p.L346= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs749811229; called by muse, mutect2, varscan2
- LEPROTL1 | c.336T>G p.T112= | Silent (SNP) | VAF 130/310 reads (42%) | called by muse, mutect2, varscan2
- OBP2B | c.30C>T p.L10= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs782601503; called by muse, mutect2, varscan2
- PLA2G4A | c.1977T>A p.T659= | Silent (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- POU6F2 | c.1047G>A p.L349= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as rs1422111351, COSV101302853; called by muse, varscan2
- PRX | c.2814C>A p.L938= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- RTL5 | c.372C>T p.P124= | Silent (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2, varscan2
- SOX8 | c.411C>T p.G137= | Silent (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5541G>A p.Q1847= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as rs772532941; called by muse, mutect2, varscan2
- UBE2I | c.405G>A p.T135= | Silent (SNP) | VAF 95/225 reads (42%) | catalogued as rs542048272; called by muse, mutect2, varscan2
- ADCY2 | c.*2226G>A | 3'UTR (SNP) | VAF 41/79 reads (52%) | called by muse, mutect2, varscan2
- ANKRD34B | c.*780C>A | 3'UTR (SNP) | VAF 23/63 reads (37%) | catalogued as rs886354044; called by muse, mutect2, varscan2
- APBB3 | c.-55T>A | 5'UTR (SNP) | VAF 63/128 reads (49%) | called by muse, mutect2, varscan2
- BEND4 | c.*3688G>A | 3'UTR (SNP) | VAF 29/34 reads (85%) | catalogued as rs1032243188; called by muse, mutect2, varscan2
- BTN3A3 | c.434-98T>C | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- C3orf35 | n.1375C>T | RNA (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- CDH8 | c.-44dup | 5'UTR (INS) | VAF 24/67 reads (36%) | catalogued as rs746335090; called by mutect2, varscan2
- CENPB | c.*307C>T | 3'UTR (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- CHL1 | chr3:409020 G>A | 3'Flank (SNP) | VAF 3/41 reads (7%) | catalogued as rs1325117190; called by muse, mutect2
- CNKSR3 | c.-456A>C | 5'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- CREB5 | c.*6002C>G | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- CYHR1 | c.247-2461G>T | Intron (SNP) | VAF 37/92 reads (40%) | called by muse, varscan2
- DENND5A | c.949+94T>C | Intron (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2
- DIP2C | c.*3115T>G | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- EGLN1 | c.*2000C>T | 3'UTR (SNP) | VAF 49/81 reads (60%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.*5775C>T | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- EIF5 | c.*169C>T | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- ELK4 | c.*5796A>G | 3'UTR (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- FAM120A | c.1734+1013C>T | Intron (SNP) | VAF 9/69 reads (13%) | catalogued as rs957790101; called by muse, mutect2, varscan2
- FBN2 | c.-577G>T | 5'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- FBXW8 | chr12:117029708 C>G | 3'Flank (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
- FZD4 | c.*3864G>A | 3'UTR (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- GABRA4 | c.*219C>T | 3'UTR (SNP) | VAF 17/19 reads (89%) | called by muse, mutect2, varscan2
- GABRG2 | chr5:162067655 G>T | 5'Flank (SNP) | VAF 50/88 reads (57%) | called by muse, mutect2, varscan2
- GBP1P1 | n.1580T>C | RNA (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- GBP5 | c.1363-47C>G | Intron (SNP) | VAF 32/261 reads (12%) | catalogued as rs768565499; called by muse, mutect2, varscan2
- GCSAML | c.*2636T>C | 3'UTR (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- GDNF | c.*2908C>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, varscan2
- GPR84 | c.*10C>T | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, varscan2
- HNRNPCP2 | n.476G>A | RNA (SNP) | VAF 38/65 reads (58%) | called by muse, mutect2, varscan2
- KAT7 | c.*558G>C | 3'UTR (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- KIAA1109 | c.*301T>G | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- KIAA1143P1 | n.375C>T | RNA (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- KIF2B | c.-85G>T | 5'UTR (SNP) | VAF 18/40 reads (45%) | called by mutect2, varscan2
- KLF4 | c.6-31C>T | Intron (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- LIMD1 | c.*174C>T | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- LMO7 | c.1307+41C>T | Intron (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- LNPEP | c.*1271G>T | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- LY6K | c.*450C>T | 3'UTR (SNP) | VAF 41/95 reads (43%) | catalogued as rs782321006; called by muse, mutect2, varscan2
- METTL2A | c.*3891G>A | 3'UTR (SNP) | VAF 59/155 reads (38%) | called by muse, mutect2, varscan2
- MIEF2 | c.*971G>T | 3'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as COSV59902238; called by muse, mutect2, varscan2
- MSL3 | c.102+300G>A | Intron (SNP) | VAF 38/43 reads (88%) | catalogued as COSV100384834; called by muse, mutect2, varscan2
- MYO1E | c.-198C>G | 5'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- NCAPD3 | c.*2365C>G | 3'UTR (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- NPAT | c.*1384C>G | 3'UTR (SNP) | VAF 50/55 reads (91%) | called by muse, mutect2, varscan2
- OTOF | c.*349C>T | 3'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- PAX6 | c.142-182C>T | Intron (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- PAX6 | c.10+692T>G | Intron (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- PHF6 | c.968+1086A>C | Intron (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- PYGO1 | c.*5617G>C | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2
- RMND1 | c.*250G>A | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- RNF149 | c.*927C>G | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- RNF165 | c.61+31G>A | Intron (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- SASH1 | c.*280C>T | 3'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- SDC2 | c.*2074G>A | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- SEC16B | c.1775+255T>C | Intron (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- SHQ1 | c.*167G>C | 3'UTR (SNP) | VAF 51/123 reads (41%) | called by muse, mutect2, varscan2
- SLC13A1 | c.99+9370T>G | Intron (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- SLC26A2 | c.*4950C>G | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- SLC30A9 | c.*1125dup | 3'UTR (INS) | VAF 12/14 reads (86%) | catalogued as rs1337719119; called by mutect2, varscan2
- SLC5A2 | c.1022-88G>A | Intron (SNP) | VAF 22/54 reads (41%) | catalogued as rs537526690; called by muse, mutect2, varscan2
- SLCO1A2 | c.*2928G>A | 3'UTR (SNP) | VAF 50/85 reads (59%) | called by muse, mutect2, varscan2
- SMIM4 | c.-116G>C | 5'UTR (SNP) | VAF 61/147 reads (41%) | catalogued as rs1032427066; called by muse, mutect2, varscan2
- SNX13 | c.2626+646A>T | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- STRAP | c.-284G>A | 5'UTR (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- STX7 | c.*1754T>C | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, varscan2
- SULT1E1 | c.*198C>A | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- TAF5L | c.*282C>T | 3'UTR (SNP) | VAF 103/343 reads (30%) | catalogued as rs987730544; called by muse, mutect2
- TENT5A | c.*1236C>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3360T>G | 3'UTR (SNP) | VAF 81/193 reads (42%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+167G>A | Intron (SNP) | VAF 46/111 reads (41%) | catalogued as rs985996018; called by muse, mutect2, varscan2
- TOMM70 | c.*1387C>T | 3'UTR (SNP) | VAF 48/103 reads (47%) | catalogued as rs758849185; called by muse, mutect2, varscan2
- UNC5A | c.*14C>T | 3'UTR (SNP) | VAF 66/128 reads (52%) | catalogued as rs373776635, COSV99458601; called by muse, mutect2, varscan2
- UTP25 | c.*518C>T | 3'UTR (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- ZIC1 | c.*1573C>T | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
